Somatic mutation profile of tumor specimen TCGA-BR-8284-01A (aliquot TCGA-BR-8284-01A-11D-2340-08) from TCGA case TCGA-BR-8284, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.6 years (26,526 days).
Specimen TCGA-BR-8284-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 003c71bc-dd16-47bb-a664-8ad58ccdb385.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8284-10A (Blood Derived Normal), aliquot TCGA-BR-8284-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49c2a0b3-596f-4288-844d-bec7101626f7

The open-access MAF lists 327 somatic variants for this specimen: 240 protein-altering or splice-affecting, 78 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 184, Silent 78, Frame Shift Del 26, Nonsense Mutation 16, Splice Site 7, Frame Shift Ins 4, Splice Region 3, 3'Flank 3, Intron 2, RNA 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NDUFS6 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs863224110, COSV56876178; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 16/100 reads (16%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 16/105 reads (15%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA13 | c.10566C>A p.Y3522* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV71284327; called by muse, mutect2, varscan2
- ABCG2 | c.1093A>G p.K365E | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV52943942; called by muse, mutect2, varscan2
- ABHD6 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.498); catalogued as rs34260150; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 42/106 reads (40%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM15 | c.2309del p.P770Lfs*35 (on ENST00000356955 / NM_207197.3; = p.P770Lfs*52 on NM_207194.3) | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | catalogued as rs758144914; called by mutect2, pindel, varscan2
- ADAMTS10 | c.2293del p.Q765Sfs*7 | Frame Shift Del (DEL) | VAF 11/81 reads (14%) | catalogued as rs782743337; called by mutect2, varscan2
- ADAMTSL3 | c.3380A>G p.E1127G | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99717277; called by muse, mutect2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 17/87 reads (20%) | catalogued as rs760140619; called by mutect2, varscan2
- AGR3 | c.368A>G p.D123G | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60037347; called by muse, mutect2
- ALDH8A1 | c.1184C>A p.P395Q | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55640495; called by muse, mutect2, varscan2
- ALG10B | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV58142548; called by muse, mutect2
- ANAPC2 | c.1839G>T p.E613D | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV60568772; called by muse, mutect2
- AP002512.3 | c.144+6T>C | Splice Region (SNP) | VAF 7/145 reads (5%) | catalogued as COSV56565998; called by muse, mutect2
- AP002748.5 | c.1024G>T p.G342C | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM031134, COSV100567719; called by muse, mutect2
- AP1B1 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1322502108, COSV58015095; called by muse, mutect2
- ARHGEF40 | c.2626C>T p.R876C | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs370713697; called by muse, mutect2, varscan2
- ARID1A | c.5125-1G>A p.X1709_splice | Splice Site (SNP) | VAF 161/332 reads (48%) | catalogued as COSV61373017; called by muse, mutect2, varscan2
- ARID1B | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.035); catalogued as COSV51651427; called by muse, mutect2, varscan2
- ATP10D | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56704778; called by muse, mutect2, varscan2
- ATP2B3 | c.2506G>A p.V836I | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs1221371446, COSV54841944; called by muse, mutect2, varscan2
- ATP6V0A2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs769927427, COSV57747972; called by muse, mutect2
- ATP7A | c.1235T>C p.L412P | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58443472; called by muse, mutect2, varscan2
- BACE1 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV56117880; called by muse, mutect2, varscan2
- BCHE | c.1283G>T p.C428F | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52254273; called by muse, mutect2, varscan2
- BICD2 | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV63548173; called by muse, mutect2
- BRWD3 | c.2761G>T p.E921* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100955704; called by muse, mutect2, varscan2
- C10orf90 | c.1703G>C p.R568T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV52950577; called by muse, mutect2, varscan2
- C1S | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.51); catalogued as rs375077429, COSV61070272; called by muse, mutect2
- C2orf69 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60665995; called by muse, mutect2
- C3 | c.2149G>A p.G717S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.132); catalogued as COSV55568700, COSV55569909; called by muse, mutect2, varscan2
- CACNA1G | c.6211C>A p.L2071I | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as COSV61721240; called by muse, mutect2, varscan2
- CASC3 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | catalogued as COSV52866436; called by muse, varscan2
- CASC3 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52866441; called by muse, varscan2
- CASC3 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV52866452; called by muse, varscan2
- CASC3 | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV52866516; called by muse, varscan2
- CCDC57 | c.350A>T p.Q117L | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV66433039; called by muse, mutect2
- CCDC60 | c.914A>G p.E305G | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs752027529, COSV59541125; called by muse, mutect2, varscan2
- CDC6 | c.1662C>G p.I554M | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs542837328, COSV52929911; called by muse, varscan2
- CDHR5 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.085); catalogued as COSV57641747; called by muse, mutect2
- CDK16 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV52091279; called by muse, mutect2
- CDX4 | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs940984524, COSV100999108; called by muse, mutect2, varscan2
- CECR2 | c.3658A>G p.T1220A (on ENST00000342247 / NM_001290047.2; = p.T1036A on NM_001290046.1) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as COSV52837414; called by mutect2, varscan2
- CEP57L1 | c.19C>T p.H7Y | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as COSV61244319; called by muse, mutect2, varscan2
- CES5A | c.488C>A p.A163D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51864185; called by muse, mutect2, varscan2
- CHD5 | c.3397C>T p.R1133C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52409386; called by muse, mutect2, varscan2
- CLASP1 | c.3692del p.G1231Vfs*4 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | catalogued as rs749719822, COSV99752279; called by mutect2, varscan2
- CNTN4 | c.1247T>C p.V416A | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV61869120; called by muse, mutect2, varscan2
- COL4A2 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.683); catalogued as rs1384344513, COSV64625647; called by muse, mutect2, varscan2
- CPNE4 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV70191243; called by muse, mutect2
- CPO | c.167T>A p.I56N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55938902; called by muse, mutect2, varscan2
- CPXCR1 | c.9T>A p.Y3* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV52161359; called by muse, mutect2
- CRISP1 | c.623C>A p.T208N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100237140, COSV59992969, COSV59995583; called by muse, mutect2
- CSMD3 | c.1984G>T p.E662* (on ENST00000297405 / NM_001363185.1; = p.E558* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 18/170 reads (11%) | catalogued as COSV52119892; called by muse, mutect2, varscan2
- CUX1 | c.1289del p.P430Lfs*27 | Frame Shift Del (DEL) | VAF 10/107 reads (9%) | catalogued as rs782381199; called by mutect2, pindel, varscan2
- DCLK1 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1237880518, COSV55172983; called by muse, mutect2, varscan2
- DCTN1 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 28/391 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62619770; called by muse, mutect2
- DDI1 | c.664A>T p.N222Y | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56370600; called by muse, mutect2
- DGCR8 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as rs759142349, COSV61225904; called by muse, mutect2
- DGKE | c.744G>T p.Q248H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM149474, COSV52349074; called by muse, mutect2, varscan2
- DMD | c.10315C>A p.H3439N | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV58895635; called by muse, mutect2, varscan2
- DNAAF4 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs974724008, COSV58247043; called by muse, mutect2
- DNAH9 | c.11461G>T p.A3821S | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.284); catalogued as COSV52338378; called by muse, mutect2, varscan2
- DNTT | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1377933772, COSV64522736; called by muse, mutect2
- DSEL | c.2153T>C p.V718A | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.325); catalogued as COSV59489905; called by muse, mutect2, varscan2
- DUSP26 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as rs1488143221, COSV56361002; called by muse, mutect2
- EBF1 | c.1191+2T>C p.X397_splice | Splice Site (SNP) | VAF 22/161 reads (14%) | catalogued as COSV58169823; called by muse, mutect2, varscan2
- ECRG4 | c.285G>A p.A95= | Splice Region (SNP) | VAF 8/94 reads (9%) | catalogued as rs183729457, COSV53000014; called by muse, mutect2
- EP400 | c.7156C>T p.R2386W | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1297355376; called by muse, mutect2
- EPC1 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs779179625, COSV53923600; called by muse, mutect2, varscan2
- EPHB2 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs777940741, COSV65859776; called by muse, mutect2, varscan2
- EPX | c.789C>A p.C263* | Nonsense Mutation (SNP) | VAF 22/93 reads (24%) | catalogued as COSV56595317; called by muse, mutect2, varscan2
- ETV3L | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs893426995, COSV71901217; called by muse, mutect2, varscan2
- EVC2 | c.1983G>T p.K661N | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV60388753; called by muse, mutect2, varscan2
- FAM71B | c.1292G>T p.R431I | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV57227891; called by muse, mutect2
- FAM90A1 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs759052041, COSV56710439; called by mutect2, varscan2
- FAN1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.129); catalogued as rs137920161, COSV62949859; called by muse, mutect2, varscan2
- FASN | c.3499G>T p.A1167S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as rs758283388, COSV60751360; called by muse, mutect2, varscan2
- FBN2 | c.3792C>G p.Y1264* | Nonsense Mutation (SNP) | VAF 14/216 reads (6%) | catalogued as COSV52497474; called by muse, mutect2
- FCRL2 | c.110A>C p.K37T | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV63832874; called by muse, mutect2, varscan2
- FCRL6 | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58940211; called by muse, mutect2
- FGD4 | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV56781047; called by muse, mutect2
- FGF10 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV99240159; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 6/67 reads (9%) | catalogued as rs777980924; called by mutect2, pindel
- FMR1 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV54422258; called by muse, mutect2, varscan2
- FRAS1 | c.11711C>T p.A3904V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as rs750578354, COSV53594701; called by muse, mutect2, varscan2
- GABRA4 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV51923763; called by muse, mutect2
- GIMAP6 | c.142A>G p.K48E | Missense Mutation (SNP) | VAF 37/527 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61032685; called by muse, mutect2
- GPR45 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV51522825; called by muse, mutect2, varscan2
- GRIK5 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs751946918, COSV53475700; called by muse, mutect2
- H1-5 | c.635A>G p.K212R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.19); catalogued as COSV58899267; called by muse, mutect2, varscan2
- H2BC11 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); catalogued as rs768243833, COSV60361779; called by muse, mutect2, varscan2
- HAP1 | c.714G>A p.E238= | Splice Region (SNP) | VAF 13/70 reads (19%) | catalogued as COSV57877592; called by muse, mutect2, varscan2
- HEPH | c.2843C>T p.P948L (on ENST00000343002; = p.P681L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV100294524, COSV57960255, COSV57965431; called by muse, mutect2, varscan2
- HESX1 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.751); catalogued as COSV99907679; called by muse, mutect2
- HIVEP1 | c.8110G>A p.D2704N | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs760461967, COSV65099336, COSV65105172; called by muse, mutect2, varscan2
- HTATIP2 | c.304-2A>G p.X102_splice | Splice Site (SNP) | VAF 14/118 reads (12%) | catalogued as rs748008659, COSV70041046; called by muse, mutect2, varscan2
- HTATSF1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs1477426617, COSV54477632; called by muse, mutect2, varscan2
- IL10RA | c.322C>A p.H108N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.159); catalogued as COSV57139899; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | catalogued as rs760925109; called by mutect2, pindel
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNA4 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV60251002; called by muse, mutect2, varscan2
- KIF4B | c.3020C>A p.P1007H | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as rs1016306406, COSV70528207, COSV70529173; called by muse, mutect2
- KRT81 | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs758856533, COSV59809252; called by muse, mutect2, varscan2
- LRRC4B | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV65349420; called by muse, mutect2, varscan2
- LRRC8D | c.2050C>T p.R684* | Nonsense Mutation (SNP) | VAF 6/103 reads (6%) | catalogued as COSV61577903; called by muse, mutect2
- LRRTM1 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54438961; called by muse, mutect2
- MACROH2A1 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100427555; called by muse, mutect2
- MAGEE1 | c.2514G>C p.L838F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63909115; called by muse, mutect2, varscan2
- MC1R | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.075); catalogued as COSV59624624, COSV59625806; called by muse, mutect2, varscan2
- MICAL1 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as rs559938192, COSV62192306; called by muse, mutect2
- MKX | c.615G>T p.E205D | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1478135013, COSV65391665; called by muse, mutect2, varscan2
- MLLT3 | c.124A>G p.S42G | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.137); catalogued as COSV63495461; called by muse, mutect2
- MSN | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); catalogued as COSV64303496; called by muse, mutect2, varscan2
- MSN | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1417887388, COSV64303309; called by muse, mutect2
- MYO1F | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369105985; called by muse, mutect2, varscan2
- MYO7A | c.3595G>A p.V1199M | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs782151104, COSV68683761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAB1 | c.543del p.A182Rfs*34 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | catalogued as COSV61608953; called by mutect2, pindel, varscan2
- NALCN | c.4820G>A p.R1607Q | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs370886839, COSV99218045; called by muse, mutect2, varscan2
- NIPSNAP3B | c.448G>T p.V150F | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV66106427; called by muse, mutect2, varscan2
- NLRX1 | c.428del p.P143Hfs*81 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs767102699; called by mutect2, varscan2
- NOTCH3 | c.5089G>A p.V1697M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs971041880, COSV54625693, COSV54640662; called by muse, mutect2, varscan2
- NPC1L1 | c.284A>T p.Q95L | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56923027; called by muse, mutect2
- NPFFR2 | c.278C>A p.A93D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.154); catalogued as COSV58147448; called by muse, mutect2, varscan2
- NR4A3 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs529538777, COSV58243670; called by muse, mutect2, varscan2
- NTRK2 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs997635600, COSV52856453; called by muse, mutect2, varscan2
- NTRK2 | c.1697A>C p.K566T (on ENST00000323115 / NM_001369534.1; = p.K582T on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52856485; called by muse, mutect2, varscan2
- NUP214 | c.681del p.V228Sfs*29 | Frame Shift Del (DEL) | VAF 8/63 reads (13%) | catalogued as rs771913112, COSV63912486; called by mutect2, varscan2
- OPRK1 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99653751; called by mutect2, varscan2
- OR2A25 | c.801G>T p.K267N | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV68716932, COSV68716938; called by muse, mutect2
- OR2A5 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV68738554; called by muse, mutect2, varscan2
- OR2L13 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63549238; called by muse, mutect2, varscan2
- OR51E1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs760647045, COSV67809478, COSV67810339; called by muse, mutect2, varscan2
- OR52L1 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.187); catalogued as COSV59986026, COSV59988219; called by muse, mutect2, varscan2
- OSBPL10 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.075); catalogued as rs990677677, COSV104429801, COSV67335639; called by muse, mutect2
- OSBPL3 | c.905A>G p.H302R | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57653757; called by muse, mutect2, varscan2
- P2RX2 | c.187G>A p.V63M (on ENST00000343948 / NM_170683.4; = p.R40H on NM_012226.5) | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as COSV57675396; called by muse, varscan2
- P2RY10 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 35/294 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs746304449, COSV50680309; called by muse, mutect2, varscan2
- PATZ1 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.245); catalogued as COSV99315120; called by muse, mutect2
- PBRM1 | c.3553C>T p.R1185* (on ENST00000296302 / NM_001366071.2; = p.R1160* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV56264314; called by muse, mutect2, varscan2
- PCDH10 | c.1906G>A p.G636R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429679034, COSV52088867; called by muse, mutect2, varscan2
- PCDH9 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs778185688, COSV60533168, COSV60569030; called by muse, mutect2, varscan2
- PCDHAC2 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53839598; called by muse, mutect2
- PCDHB15 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV50862136, COSV50879300; called by muse, mutect2
- PCDHGA12 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52745510; called by muse, mutect2
- PDGFD | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 14/78 reads (18%) | catalogued as COSV56370586; called by muse, mutect2, varscan2
- PI4KA | c.5008C>T p.R1670W | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1050137675, COSV55405880; called by muse, mutect2, varscan2
- PIAS3 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs142217740; called by muse, mutect2
- PKD1L1 | c.1046A>G p.H349R | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV56959459; called by muse, mutect2
- PKLR | c.644del p.G215Afs*12 | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | catalogued as CD090472; called by mutect2, pindel, varscan2
- PLEC | c.13414G>A p.A4472T (on ENST00000322810 / NM_201380.4; = p.A4362T on NM_000445.5) | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416802915, COSV59610211; called by muse, mutect2
- PLXDC1 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370370043; called by muse, mutect2, varscan2
- PLXNA4 | c.5077G>A p.D1693N | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV58109643, COSV58153690; called by muse, mutect2
- POLR2E | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs1406420756, COSV53123485; called by muse, mutect2, varscan2
- POLR3E | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs371107234; called by muse, mutect2, varscan2
- PRAG1 | c.3848G>A p.R1283Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.966); catalogued as rs377087982; called by muse, mutect2, varscan2
- PRAMEF14 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.379); catalogued as rs555251277, COSV100577267; called by muse, mutect2, varscan2
- PRELP | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58114995; called by muse, mutect2
- PRKX | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53322482; called by muse, mutect2
- RANBP3L | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs751770258, COSV56954604; called by muse, mutect2, varscan2
- REXO5 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs897879878, COSV54470934; called by muse, mutect2
- RHD | c.359C>A p.A120D | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs868537949, COSV59645446; called by muse, mutect2, varscan2
- RNF213 | c.14842G>A p.V4948M | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs375652626; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPTOR | c.1741C>T p.L581F | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60804458; called by muse, mutect2, varscan2
- RSPO3 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 12/109 reads (11%) | catalogued as COSV63149852; called by muse, mutect2, varscan2
- SCUBE2 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.91); catalogued as rs367701920; called by muse, mutect2, varscan2
- SDK1 | c.4384G>A p.E1462K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.592); catalogued as COSV67359169, COSV67378124; called by muse, mutect2
- SEMA4A | c.1134+1G>A p.X378_splice | Splice Site (SNP) | VAF 9/70 reads (13%) | catalogued as rs1267961750, COSV61772226, COSV61773172; called by muse, mutect2, varscan2
- SEMA5B | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767647903, COSV52091368; called by muse, mutect2
- SEMA6D | c.1753G>A p.G585S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs150769593; called by muse, mutect2, varscan2
- SERPINI2 | c.648G>T p.M216I | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV52984766, COSV52987267; called by muse, mutect2, varscan2
- SIPA1L3 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs1221926526, COSV55909965; called by muse, mutect2, varscan2
- SLC23A2 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs751107544, COSV57771608; called by muse, mutect2
- SLC45A4 | c.812C>T p.A271V (on ENST00000517878 / NM_001286646.2; = p.A220V on NM_001080431.2) | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.035); catalogued as COSV50133934; called by muse, mutect2, varscan2
- SLC5A5 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV55831681; called by muse, mutect2
- SLC7A5 | c.1186G>A p.V396I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs149119495; called by mutect2, varscan2
- SLC9A5 | c.1262G>T p.R421M | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV55360746; called by muse, mutect2, varscan2
- SLFN13 | c.548T>C p.I183T | Missense Mutation (SNP) | VAF 7/184 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV99539771; called by muse, mutect2
- SMAD5 | c.1256G>A p.G419D | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72596906; called by muse, mutect2
- SMG9 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs1032908644, COSV54213893; called by muse, mutect2
- SOCS5 | c.128A>G p.K43R | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV60604031; called by muse, mutect2, varscan2
- SOX6 | c.2087G>A p.R696H (on ENST00000528429 / NM_001145819.2; = p.R669H on NM_017508.3) | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57036569; called by muse, mutect2
- SP4 | c.1960T>C p.C654R | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56021102; called by muse, mutect2
- SPTBN5 | c.10121G>A p.R3374Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs542603385, COSV58017487; called by muse, mutect2, varscan2
- SSH2 | c.3023G>A p.R1008K | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV52167661; called by muse, mutect2, varscan2
- STAM2 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as COSV55730000; called by muse, mutect2
- SYNDIG1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs768001570, COSV65232692; called by muse, mutect2, varscan2
- TAF1L | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as rs1415581932, COSV54258694; called by muse, mutect2
- TAF7 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57664903; called by muse, mutect2
- TBX22 | c.413A>G p.Y138C | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64785168; called by muse, mutect2
- TCF21 | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52817974; called by muse, mutect2
- TFAP4 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52596985; called by muse, mutect2
- TFPT | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV57837201; called by muse, mutect2
- TGFBR3 | c.2156A>G p.K719R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV53022521; called by muse, mutect2
- TLL1 | c.2031G>T p.E677D | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1234703820, COSV50263893; called by muse, mutect2, varscan2
- TMEM79 | c.179A>G p.E60G | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV55293584; called by muse, mutect2, varscan2
- TNNI3K | c.2200A>C p.S734R | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.986); catalogued as COSV53946162; called by muse, mutect2, varscan2
- TOMM70 | c.1130A>T p.Y377F | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.219); catalogued as COSV52522486; called by muse, mutect2
- TRIM72 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs887056269, COSV59066868; called by muse, mutect2, varscan2
- TRPM5 | c.2564T>A p.I855K | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1454527252, COSV50145632; called by muse, mutect2, varscan2
- TTN | c.91502T>C p.V30501A (on ENST00000591111; = p.V23077A on NM_003319.4) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | PolyPhen benign (0.058); catalogued as COSV59919975; called by muse, mutect2, varscan2
- UBXN7 | c.615+1G>A p.X205_splice | Splice Site (SNP) | VAF 13/131 reads (10%) | catalogued as COSV56354191; called by muse, mutect2, varscan2
- UCKL1 | c.1471G>A p.V491M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs1386476535, COSV62402417; called by muse, mutect2, varscan2
- USP6 | c.2150T>C p.M717T | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.801); catalogued as COSV51476694; called by muse, mutect2, varscan2
- UTP20 | c.3055C>T p.R1019* | Nonsense Mutation (SNP) | VAF 12/94 reads (13%) | catalogued as COSV55371671; called by muse, mutect2, varscan2
- VDAC1 | c.628T>C p.W210R | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54736804; called by muse, mutect2
- VPS8 | c.1063G>A p.A355T (on ENST00000625842 / NM_001349294.1; = p.A353T on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV54981523; called by muse, mutect2
- VRK2 | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV60875153; called by muse, mutect2, varscan2
- YARS1 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | catalogued as COSV65114108; called by muse, mutect2
- YTHDC1 | c.1691T>C p.L564S (on ENST00000344157 / NM_001031732.4; = p.L546S on NM_133370.4) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as COSV60009065; called by muse, mutect2, varscan2
- ZFP42 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58816630, COSV58819685; called by mutect2, varscan2
- ZIC1 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV51555799; called by muse, mutect2
- ZIM3 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs774474471, COSV54140013; called by muse, mutect2, varscan2
- ZNF205 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV54620110; called by muse, mutect2
- ZNF236 | c.2370G>A p.M790I | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV53483595; called by muse, mutect2
- ZNF341 | c.742-1G>T p.X248_splice | Splice Site (SNP) | VAF 18/259 reads (7%) | catalogued as COSV61006778; called by muse, mutect2
- ZNF350 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 22/191 reads (12%) | catalogued as rs770149500, COSV54707911; called by muse, mutect2, varscan2
- ZNF621 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs376957315; called by muse, mutect2, varscan2
- ZNF626 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV74129061, COSV99081904; called by muse, mutect2
- ABCC1 | c.133dup p.Y45Lfs*17 | Frame Shift Ins (INS) | VAF 8/103 reads (8%) | called by mutect2, pindel
- ARID4A | c.2316del p.F772Lfs*33 | Frame Shift Del (DEL) | VAF 8/79 reads (10%) | called by mutect2, pindel
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- CLK3 | c.1261+2dup p.X421_splice (on ENST00000395066 / NM_001130028.1; = p.X273_splice on NM_003992.4) | Splice Site (INS) | VAF 20/81 reads (25%) | called by mutect2, pindel, varscan2
- CTNND1 | c.2523del p.E842Kfs*10 (on ENST00000399050 / NM_001085458.2; = p.E836Kfs*10 on NM_001331.3) | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- DNAI4 | c.2162dup p.L721Ffs*48 | Frame Shift Ins (INS) | VAF 15/138 reads (11%) | called by mutect2, pindel, varscan2
- EPG5 | c.5704del p.Y1902Ifs*26 | Frame Shift Del (DEL) | VAF 11/100 reads (11%) | called by mutect2, pindel, varscan2
- FLOT2 | c.193del p.V65* | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | called by mutect2, pindel, varscan2
- FOXD4 | c.1050del p.C351Afs*57 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, varscan2
- FRG2C | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- HSP90AB1 | c.1220dup p.N407Kfs*4 | Frame Shift Ins (INS) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- IGKV1-6 | c.253A>G p.S85G | Missense Mutation (SNP) | VAF 22/237 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- POLQ | c.4289del p.L1430* | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- RGS18 | c.443del p.P148Qfs*46 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- TBCD | c.2812del p.H938Tfs*20 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel, varscan2
- TRIP4 | c.267del p.D90Mfs*4 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- XYLT2 | c.1763dup p.L588Ffs*11 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- ACVRL1 | c.924C>T p.C308= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as CM970047; called by muse, mutect2
- ADCY2 | c.687G>A p.S229= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as rs149422716, COSV100602184, COSV100604359; called by muse, mutect2, varscan2
- ALCAM | c.1056G>A p.V352= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as COSV60246065; called by muse, mutect2, varscan2
- ARHGAP5 | c.1953C>T p.A651= | Silent (SNP) | VAF 21/164 reads (13%) | catalogued as rs757953107, COSV61534234; called by muse, mutect2, varscan2
- ARRDC4 | c.1221C>T p.D407= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as rs557916017, COSV51418677; called by muse, mutect2, varscan2
- ATP13A5 | c.507G>A p.L169= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as COSV100665817, COSV60866683; called by muse, mutect2, varscan2
- BOD1L1 | c.1878A>G p.E626= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs531586027, COSV50007580; called by muse, mutect2
- BTN2A2 | c.606C>T p.D202= | Silent (SNP) | VAF 13/123 reads (11%) | catalogued as rs752559720, COSV61856764; called by muse, mutect2, varscan2
- BTN3A2 | c.642C>T p.S214= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as rs772646064, COSV62686863; called by muse, mutect2
- CASC3 | c.1881C>T p.V627= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as COSV52866494; called by muse, varscan2
- CASC3 | c.2070C>T p.I690= | Silent (SNP) | VAF 26/150 reads (17%) | catalogued as COSV52866527; called by muse, varscan2
- CHST1 | c.129C>T p.A43= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs1564996751, COSV57322126; called by muse, mutect2, varscan2
- CHST5 | c.318C>T p.S106= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs1157705334, COSV60337449; called by muse, mutect2, varscan2
- CLEC16A | c.2709C>T p.S903= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs772244955, COSV55488750; called by muse, mutect2, varscan2
- CPEB4 | c.372G>A p.S124= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as rs920565677, COSV54170095; called by muse, mutect2, varscan2
- CTRL | c.309C>T p.S103= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs893156952, COSV52122584; called by muse, mutect2, varscan2
- CXXC5 | c.234G>A p.P78= | Silent (SNP) | VAF 15/142 reads (11%) | catalogued as rs745505391, COSV56793200; called by muse, varscan2
- DDIT4L | c.387C>T p.S129= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs954060552, COSV56767049; called by muse, mutect2, varscan2
- DDX28 | c.1431G>A p.T477= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100192904; called by muse, mutect2
- DFFB | c.126C>T p.R42= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV58214792; called by muse, mutect2, varscan2
- DNAH17 | c.6213C>T p.I2071= | Silent (SNP) | VAF 23/167 reads (14%) | catalogued as rs777016911, COSV67750223; called by muse, mutect2, varscan2
- DNAH17 | c.5598C>T p.T1866= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV101101587; called by muse, mutect2
- EFCAB6 | c.2364T>C p.L788= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV53059408; called by muse, mutect2, varscan2
- EPHB2 | c.2007C>T p.S669= (on ENST00000400191 / NM_001309193.2; = p.S670= on NM_004442.7) | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs751175904, COSV65860347; called by muse, mutect2, varscan2
- FAM149A | c.987C>T p.P329= (on ENST00000356371 / NM_001367768.2; = p.P38= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 40/180 reads (22%) | catalogued as rs1450865201, COSV57026096; called by muse, mutect2, varscan2
- FAM47A | c.963G>A p.P321= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs1162317680, COSV60494548; called by muse, mutect2, varscan2
- GAPVD1 | c.570T>C p.F190= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV52921140; called by muse, mutect2
- GRIN2A | c.4114A>C p.R1372= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV58023458; called by muse, mutect2, varscan2
- H3C13 | c.6C>G p.A2= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV58943850; called by muse, mutect2, varscan2
- HAP1 | c.216G>A p.S72= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV57877603; called by muse, mutect2, varscan2
- HERC2 | c.8040T>C p.I2680= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV55311531; called by muse, mutect2
- HOXB5 | c.579C>T p.D193= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV53312261, COSV99494422; called by muse, mutect2
- INTS3 | c.3066G>A p.T1022= | Silent (SNP) | VAF 20/169 reads (12%) | catalogued as rs960734961, COSV55162399; called by muse, mutect2, varscan2
- IPCEF1 | c.846T>C p.S282= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV54541307; called by muse, mutect2, varscan2
- IRAK3 | c.1560C>T p.D520= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as rs535365734, COSV54159897; called by muse, mutect2, varscan2
- IRS1 | c.786T>C p.D262= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs769620804, COSV59334201; called by muse, mutect2, varscan2
- ISLR2 | c.501C>T p.F167= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV62301618; called by muse, mutect2
- ITGA11 | c.726G>A p.T242= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs376065060, COSV59880759; called by muse, mutect2, varscan2
- KIF26B | c.1224T>G p.S408= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV63637949; called by muse, mutect2
- KIF2B | c.930G>A p.T310= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs139246128; called by muse, mutect2, varscan2
- LCP2 | c.1218T>G p.P406= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV50447336; called by muse, mutect2, varscan2
- LRRC8C | c.477C>A p.I159= | Silent (SNP) | VAF 21/133 reads (16%) | catalogued as rs34247046; called by muse, mutect2, varscan2
- MAP3K6 | c.2556C>T p.L852= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs755931721, COSV58870552; called by muse, mutect2, varscan2
- MDN1 | c.9969C>T p.Y3323= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as rs1209498071, COSV65518323; called by muse, mutect2
- MEN1 | c.1425G>A p.P475= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs1060503795, COSV53641026; ClinVar: likely benign; called by muse, mutect2, varscan2
- MGAT5B | c.258C>T p.D86= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs149427118; called by muse, mutect2, varscan2
- MMP24 | c.795G>A p.T265= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as rs554368304, COSV55768753; called by muse, mutect2
- MYCT1 | c.381C>A p.R127= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as rs768361552, COSV65890895; called by muse, mutect2
- NDNF | c.69C>T p.P23= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV65632776; called by muse, mutect2
- NRG2 | c.1752C>T p.R584= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs780957553, COSV56830194; called by muse, mutect2, varscan2
- OR11H4 | c.927C>T p.L309= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as rs546964551, COSV59559821; called by muse, mutect2, varscan2
- OR2W3 | c.117C>T p.L39= | Silent (SNP) | VAF 40/171 reads (23%) | catalogued as rs758275599, COSV64456256; called by muse, mutect2, varscan2
- PLEKHF1 | c.813G>C p.G271= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV71409970; called by muse, mutect2, varscan2
- POGZ | c.2793G>A p.P931= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs780310461, COSV51850615; ClinVar: likely benign; called by muse, mutect2, varscan2
- POLA1 | c.2055C>A p.T685= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV100985071; called by muse, mutect2, varscan2
- POLE | c.3045C>T p.D1015= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs753809068, COSV57675404; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRKN | c.1260C>T p.R420= | Silent (SNP) | VAF 17/166 reads (10%) | catalogued as COSV58206781; called by muse, mutect2
- PTPRU | c.2619G>A p.A873= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs764110764, COSV60523162; called by muse, mutect2, varscan2
- PXDNL | c.2682C>T p.I894= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV62481016; called by muse, mutect2, varscan2
- RDH11 | c.681G>A p.T227= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs199934972, COSV67282464; called by muse, mutect2, varscan2
- ROBO3 | c.2814G>A p.P938= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as COSV67299644; called by muse, mutect2, varscan2
- S1PR5 | c.603C>T p.F201= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV61013402; called by muse, mutect2, varscan2
- SELE | c.1488G>T p.L496= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV60974287; called by mutect2, varscan2
- SERPINB12 | c.130T>C p.L44= | Silent (SNP) | VAF 16/218 reads (7%) | catalogued as COSV54032297; called by muse, mutect2
- SFRP4 | c.642C>T p.V214= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as COSV71412262, COSV71412755; called by muse, mutect2, varscan2
- SLC10A6 | c.990C>T p.C330= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV56720979; called by muse, mutect2, varscan2
- SLC26A4 | c.261C>T p.D87= | Silent (SNP) | VAF 24/137 reads (18%) | catalogued as rs758057358, COSV55914824; called by muse, mutect2, varscan2
- SMC6 | c.1209G>A p.R403= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as rs1428711803; called by muse, mutect2
- SNX5 | c.1038C>T p.C346= | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as COSV66697649; called by muse, mutect2
- SPTY2D1 | c.1374C>A p.P458= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV60473110; called by muse, mutect2, varscan2
- STAB1 | c.6423C>T p.R2141= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs779547243, COSV58733089; called by muse, mutect2, varscan2
- SYT10 | c.1515G>A p.A505= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs199704172, COSV57338281; called by muse, mutect2, varscan2
- TEAD2 | c.132G>A p.V44= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs751785086, COSV55561710; called by muse, mutect2, varscan2
- THSD7B | c.2088A>G p.V696= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV55661953; called by muse, mutect2
- TRIM47 | c.1305C>T p.D435= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV54667755; called by muse, mutect2, varscan2
- ZAN | c.1419G>A p.A473= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as rs1004564157, COSV100770045, COSV61805384, COSV61806059; called by muse, mutect2
- ZNF324B | c.1452G>A p.T484= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs752125109, COSV60740785; called by muse, mutect2, varscan2
- ZNF521 | c.1488C>A p.I496= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV64123337, COSV64131393; called by muse, mutect2, varscan2
- AL161729.4 | chr9:95516670 C>T | 3'Flank (SNP) | VAF 5/54 reads (9%) | catalogued as COSV64593997; called by muse, mutect2
- C3orf84 | c.141+125T>G | Intron (SNP) | VAF 21/177 reads (12%) | catalogued as COSV71305626; called by muse, mutect2, varscan2
- CEP295 | c.5851-193del | Intron (DEL) | VAF 5/39 reads (13%) | catalogued as rs754124024; called by mutect2, pindel, varscan2
- EHMT1 | chr9:137838509 del C | 3'Flank (DEL) | VAF 12/89 reads (13%) | catalogued as rs749169251; called by mutect2, varscan2
- MC5R | c.-1A>G | 5'UTR (SNP) | VAF 7/132 reads (5%) | catalogued as COSV100228944; called by muse, mutect2
- NFATC4 | chr14:24367191 G>T | 5'Flank (SNP) | VAF 7/62 reads (11%) | catalogued as COSV99144490; called by muse, mutect2
- OR52A4P | chr11:5121113 G>A | 3'Flank (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- RPL26P30 | n.591G>T | RNA (SNP) | VAF 22/145 reads (15%) | called by muse, mutect2, varscan2
- SLC22A17 | n.905C>A | RNA (SNP) | VAF 10/92 reads (11%) | catalogued as COSV52834963; called by muse, mutect2, varscan2
